Somatic mutation profile of tumor specimen ALCH-B34Z-TTP1-A (aliquot ALCH-B34Z-TTP1-A-2-0-D-A78R-36) from ALCHEMIST case ALCH-B34Z, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.2 years (22,350 days).
Specimen ALCH-B34Z-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7f127151-584e-4761-a6bb-ae06419ff550.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B34Z-NB1-A (Blood Derived Normal), aliquot ALCH-B34Z-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/602de661-36ba-4f2d-953f-e675a6fa0ddb

The open-access MAF lists 568 somatic variants for this specimen: 380 protein-altering or splice-affecting, 124 silent, 64 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 330, Silent 124, Nonsense Mutation 31, Intron 30, RNA 14, 3'UTR 6, Splice Region 6, Splice Site 6, 3'Flank 6, Frame Shift Del 4, 5'UTR 4, 5'Flank 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 38/285 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.1357C>T p.R453C | Missense Mutation (SNP) | VAF 112/705 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913625, CM087715, CM920490, COSV62516285; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NUP93 | c.43C>T p.Q15* | Nonsense Mutation (SNP) | VAF 22/149 reads (15%) | hotspot (GDC flag); catalogued as COSV57428872, COSV57434100; called by muse, mutect2, varscan2
- TP53 | c.743G>T p.R248L | Missense Mutation (SNP) | VAF 39/243 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABRA | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 12/167 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs770684024, COSV61731930; called by muse, mutect2
- AC136428.1 | c.101G>C p.G34A | Missense Mutation (SNP) | VAF 19/261 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.92); catalogued as COSV101434983; called by muse, mutect2
- AC136428.1 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 20/261 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); catalogued as COSV71169137, COSV71169153, COSV71169248; called by muse, mutect2
- ACE2 | c.251C>A p.P84Q | Missense Mutation (SNP) | VAF 43/215 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.024); catalogued as COSV53023439; called by muse, mutect2, varscan2
- ADCY10 | c.2911G>A p.D971N | Missense Mutation (SNP) | VAF 44/450 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as COSV100896445; called by muse, mutect2
- AIFM2 | c.1114C>T p.P372S | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as COSV57160938; called by muse, mutect2, varscan2
- AL121899.2 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs1368754825; called by muse, mutect2
- ANK2 | c.1796C>A p.P599Q | Missense Mutation (SNP) | VAF 22/638 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99053390; called by muse, mutect2
- APEH | c.12+7G>T | Splice Region (SNP) | VAF 5/71 reads (7%) | catalogued as rs1285483100; called by muse, mutect2
- ARAP2 | c.2642C>T p.S881F | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as rs201489421; called by muse, mutect2
- ARHGAP4 | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs782325157, COSV100604046, COSV63132593; called by muse, mutect2, varscan2
- ATP2B2 | c.601G>T p.V201F | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.237); catalogued as COSV100660154, COSV100660698; called by muse, mutect2, varscan2
- ATP2B3 | c.2320G>A p.V774I | Missense Mutation (SNP) | VAF 28/222 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs1557013672; called by muse, mutect2, varscan2
- C20orf141 | c.286C>A p.R96S | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV63028326; called by muse, mutect2
- CACNG2 | c.952C>A p.R318S | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100268397; called by muse, mutect2, varscan2
- CARD6 | c.620T>C p.L207S | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs954216773; called by muse, mutect2, varscan2
- CASP8 | c.1279C>T p.Q427* (on ENST00000432109 / NM_033355.3; = p.Q444* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 20/214 reads (9%) | catalogued as COSV51851265; called by muse, mutect2
- CCDC168 | c.19365C>G p.N6455K | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.225); catalogued as rs1237026866; called by muse, mutect2, varscan2
- CCNG2 | c.353A>C p.N118T | Missense Mutation (SNP) | VAF 28/212 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.257); catalogued as COSV100313386; called by muse, mutect2, varscan2
- CFH | c.3493C>G p.H1165D | Missense Mutation (SNP) | VAF 40/578 reads (7%) | SIFT tolerated (0.88); PolyPhen benign (0.13); catalogued as CM1513712, COSV66405819; called by muse, mutect2
- CFHR2 | c.130C>A p.Q44K | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.446); catalogued as COSV66381066; called by muse, mutect2
- CLSTN1 | c.559G>T p.A187S (on ENST00000377298 / NM_001009566.3; = p.A177S on NM_014944.4) | Missense Mutation (SNP) | VAF 59/395 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1344767453; called by muse, mutect2, varscan2
- CR1 | c.3299G>C p.R1100T | Missense Mutation (SNP) | VAF 58/971 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs769092015, COSV100887466; called by muse, mutect2
- CSMD3 | c.3085G>A p.G1029S (on ENST00000297405 / NM_001363185.1; = p.G925S on NM_052900.3) | Missense Mutation (SNP) | VAF 55/317 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV52337143; called by muse, mutect2, varscan2
- DAXX | c.804C>G p.N268K | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56474000; called by muse, mutect2
- DDR2 | c.2225G>T p.R742L | Missense Mutation (SNP) | VAF 32/336 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV63370438; called by muse, mutect2
- DLL1 | c.139G>T p.G47W | Missense Mutation (SNP) | VAF 11/148 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.975); catalogued as COSV100816034; called by muse, mutect2
- DUXA | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 26/258 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as rs772135803, COSV73729702; called by muse, mutect2, varscan2
- EN1 | c.629C>A p.A210E | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.587); catalogued as rs1252410035; called by mutect2, varscan2
- ENOX2 | c.810G>T p.Q270H (on ENST00000338144 / NM_001382520.1; = p.Q241H on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/286 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV57655790; called by muse, mutect2, varscan2
- EPHB1 | c.569G>T p.R190L | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV101214339, COSV67662602; called by muse, mutect2, varscan2
- ESF1 | c.2327C>T p.S776L | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1344346689; called by muse, mutect2, varscan2
- EXO1 | c.873C>G p.I291M | Missense Mutation (SNP) | VAF 42/425 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.265); catalogued as COSV62216804; called by muse, mutect2
- EXOSC10 | c.1627G>C p.E543Q | Missense Mutation (SNP) | VAF 13/217 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.162); catalogued as rs1217852912; called by muse, mutect2
- FAM160B2 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs981331843; called by muse, mutect2, varscan2
- FAM193B | c.515C>T p.S172L | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1337149822; called by muse, mutect2, varscan2
- FAM47A | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 11/226 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV60495021; called by muse, mutect2
- FAT4 | c.10879G>T p.G3627C | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV58679853; called by muse, mutect2, varscan2
- G2E3 | c.2038G>C p.E680Q | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.037); catalogued as COSV52839741; called by muse, mutect2, varscan2
- GALNT13 | c.842G>T p.R281I | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as rs754236942; called by muse, mutect2
- GASK1B | c.460G>T p.E154* | Nonsense Mutation (SNP) | VAF 16/236 reads (7%) | catalogued as COSV56705900; called by muse, mutect2
- GNA14 | c.240C>G p.F80L | Missense Mutation (SNP) | VAF 20/303 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.063); catalogued as COSV59026433; called by muse, mutect2
- GPC4 | c.1471G>T p.D491Y | Missense Mutation (SNP) | VAF 36/205 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100895505; called by muse, mutect2, varscan2
- GRIN2B | c.3997G>A p.G1333R | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV74207159; called by muse, mutect2, varscan2
- GRK2 | c.1995G>C p.K665N | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.012); catalogued as rs1289041369; called by muse, mutect2
- INHA | c.185A>G p.H62R | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.852); catalogued as rs1470746383; called by muse, mutect2, varscan2
- JPH2 | c.1943C>A p.A648E | Missense Mutation (SNP) | VAF 45/357 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as rs1442206114, COSV65905562; called by muse, mutect2, varscan2
- KCNA5 | c.884C>A p.A295D | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs960348920; called by muse, mutect2, varscan2
- KCNH1 | c.316C>G p.P106A | Missense Mutation (SNP) | VAF 9/159 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); catalogued as COSV55106509; called by muse, mutect2
- KCNK10 | c.1514C>A p.T505K | Missense Mutation (SNP) | VAF 56/346 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.07); catalogued as COSV56649313; called by mutect2, varscan2
- KIAA0319L | c.1259C>G p.S420C | Missense Mutation (SNP) | VAF 23/256 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1171269759, COSV100357439; called by muse, mutect2
- KIAA1210 | c.1873G>T p.D625Y | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV68179125; called by muse, mutect2, varscan2
- KISS1R | c.470G>T p.R157L | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as rs1200941842; called by muse, mutect2
- KLHL4 | c.2030G>A p.G677E | Missense Mutation (SNP) | VAF 21/251 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64141741; called by muse, mutect2
- KRTAP19-5 | c.101G>A p.R34K | Missense Mutation (SNP) | VAF 48/780 reads (6%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.011); catalogued as COSV61858429; called by muse, mutect2
- KRTAP6-3 | c.118G>T p.G40W | Missense Mutation (SNP) | VAF 65/345 reads (19%) | PolyPhen probably damaging (0.959); catalogued as COSV66962684; called by muse, mutect2, varscan2
- LAMB3 | c.2146C>T p.R716W | Missense Mutation (SNP) | VAF 49/459 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs377692281; called by muse, mutect2, varscan2
- LAMC3 | c.1117C>A p.H373N | Missense Mutation (SNP) | VAF 63/423 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV63091019; called by muse, mutect2, varscan2
- LILRB3 | c.1363G>C p.E455Q (on ENST00000346401; = p.E443Q on NM_006864.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.022); catalogued as rs1170219037; called by muse, mutect2, varscan2
- MAGEC1 | c.1711G>T p.G571W | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.205); catalogued as COSV53579570; called by muse, mutect2, varscan2
- MAGEE2 | c.1459C>A p.L487I | Missense Mutation (SNP) | VAF 22/238 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1282516313; called by muse, mutect2
- MFAP1 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.802); catalogued as COSV51042083; called by muse, mutect2, varscan2
- MORN1 | c.1127C>A p.P376Q | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66006490; called by muse, mutect2, varscan2
- MRPS34 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV51598737; called by muse, mutect2, varscan2
- MTR | c.3154G>T p.V1052L | Missense Mutation (SNP) | VAF 26/212 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV63966265; called by muse, mutect2, varscan2
- MTSS2 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.617); catalogued as rs199534659, COSV104408516; called by muse, mutect2, varscan2
- MUC16 | c.32782C>A p.P10928T | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.917); catalogued as rs867409999; called by muse, mutect2, varscan2
- MXRA8 | c.185C>T p.T62I | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as rs1272753439; called by muse, mutect2, varscan2
- MYH6 | c.1144G>T p.A382S | Missense Mutation (SNP) | VAF 48/395 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as rs1330935305; called by muse, mutect2, varscan2
- NDST4 | c.1274G>T p.G425V | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52118736, COSV52137899; called by muse, mutect2
- NEB | c.4015T>A p.S1339T | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.287); catalogued as rs1247123460; called by muse, varscan2
- NID1 | c.504G>T p.R168S | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV99938066; called by muse, mutect2, varscan2
- NID2 | c.356G>A p.R119K | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs762482178, COSV53499251; called by muse, mutect2, varscan2
- NLRP3 | c.730G>T p.G244W | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100276546; called by muse, mutect2, varscan2
- NOTCH1 | c.5218G>T p.A1740S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.093); catalogued as rs864622062, CM159421, COSV53094752; ClinVar: uncertain significance; called by muse, mutect2
- NTRK1 | c.437C>G p.S146W | Missense Mutation (SNP) | VAF 29/389 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV62326131; called by muse, mutect2
- NUAK1 | c.1729G>T p.V577L | Missense Mutation (SNP) | VAF 35/221 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.025); catalogued as COSV54606523; called by muse, mutect2, varscan2
- OR2G2 | c.730T>C p.C244R | Missense Mutation (SNP) | VAF 25/232 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1411756989; called by muse, mutect2, varscan2
- OR2W3 | c.502C>A p.R168S | Missense Mutation (SNP) | VAF 25/230 reads (11%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.944); catalogued as COSV64458306; called by muse, mutect2, varscan2
- OR4C15 | c.893C>T p.A298V (on ENST00000314644; = p.A244V on NM_001001920.2) | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.149); catalogued as rs140060196, COSV100115511; called by muse, mutect2
- OR4C16 | c.342C>G p.I114M | Missense Mutation (SNP) | VAF 11/148 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.291); catalogued as rs1457615865, COSV58942378; called by muse, mutect2
- OR8K5 | c.388C>A p.L130M | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100537288, COSV57887698, COSV57891423; called by muse, mutect2, varscan2
- PCDH15 | c.5620G>T p.D1874Y | Missense Mutation (SNP) | VAF 90/638 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.275); catalogued as COSV57415229; called by muse, mutect2, varscan2
- PCDH7 | c.1265G>T p.R422L | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.052); catalogued as COSV62340093; called by muse, mutect2, varscan2
- PCNT | c.8131G>T p.E2711* | Nonsense Mutation (SNP) | VAF 13/120 reads (11%) | catalogued as COSV64025307, COSV64027585; called by muse, mutect2, varscan2
- PCNX3 | c.1207C>G p.P403A | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.587); catalogued as COSV100482616; called by muse, mutect2, varscan2
- PDZD2 | c.6073G>A p.E2025K | Missense Mutation (SNP) | VAF 29/289 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.883); catalogued as COSV56863240; called by muse, mutect2
- PEBP4 | c.269A>G p.Y90C | Missense Mutation (SNP) | VAF 13/203 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs192153678; called by muse, mutect2
- PGR | c.1186G>T p.A396S | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as rs776983648; called by muse, mutect2, varscan2
- PLEC | c.11563G>A p.E3855K (on ENST00000322810 / NM_201380.4; = p.E3745K on NM_000445.5) | Missense Mutation (SNP) | VAF 46/240 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.494); catalogued as rs201007788, COSV59641689, COSV59705192; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PNPLA3 | c.1217G>T p.R406M | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1328487998; called by muse, mutect2, varscan2
- POM121 | c.798G>T p.M266I (on ENST00000434423; = p.M1? on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/519 reads (11%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.503); catalogued as COSV57520927; called by muse, mutect2, varscan2
- POU6F2 | c.1879G>C p.E627Q | Missense Mutation (SNP) | VAF 40/577 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV68867963; called by muse, mutect2
- PRAMEF11 | c.1132C>A p.R378S | Missense Mutation (SNP) | VAF 47/362 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as COSV70819819; called by muse, mutect2, varscan2
- PRKAR2B | c.154G>A p.G52S | Missense Mutation (SNP) | VAF 28/227 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.047); catalogued as rs1430119455; called by muse, mutect2, varscan2
- PZP | c.369C>A p.N123K | Missense Mutation (SNP) | VAF 15/284 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.027); catalogued as rs746228306; called by muse, mutect2
- RGPD4 | c.3989G>C p.R1330T | Missense Mutation (SNP) | VAF 42/720 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); catalogued as rs749647242; called by muse, mutect2
- RIMS2 | c.800C>A p.P267H (on ENST00000666250 / NM_001348490.2; = p.P75H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51691625; called by muse, mutect2, varscan2
- RNF168 | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 36/574 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.402); catalogued as COSV58838509; called by muse, mutect2
- RNF19A | c.1387T>G p.S463A | Missense Mutation (SNP) | VAF 11/197 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99049615; called by muse, mutect2
- ROS1 | c.6526A>T p.T2176S | Missense Mutation (SNP) | VAF 12/217 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV63854493; called by muse, mutect2
- SAGE1 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs782532764, COSV61012906; called by muse, mutect2
- SCRIB | c.4523C>T p.S1508L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781881124; called by muse, mutect2
- SECISBP2L | c.370C>T p.H124Y | Missense Mutation (SNP) | VAF 36/495 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV99960765; called by muse, mutect2
- SIMC1 | c.455G>T p.S152I (on ENST00000443967 / NM_001308196.1; = p.S171I on NM_001308195.2) | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.724); catalogued as COSV100365799; called by muse, varscan2
- SLC30A10 | c.752G>C p.G251A | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63076449; called by muse, mutect2
- SLC9A4 | c.835T>A p.L279M | Missense Mutation (SNP) | VAF 11/216 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.217); catalogued as COSV99763461; called by muse, mutect2
- SMARCA4 | c.3763G>A p.E1255K | Missense Mutation (SNP) | VAF 13/284 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV60809046; called by muse, mutect2
- SMPD1 | c.1507G>C p.D503H | Missense Mutation (SNP) | VAF 15/216 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54970934; called by muse, mutect2
- SPATA48 | c.1228del p.R410Vfs*13 | Frame Shift Del (DEL) | VAF 28/266 reads (11%) | catalogued as COSV51667768; called by mutect2, pindel, varscan2
- STPG2 | c.1373T>C p.I458T | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.152); catalogued as rs768127331; called by muse, mutect2, varscan2
- SYMPK | c.2061G>T p.E687D | Missense Mutation (SNP) | VAF 11/143 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs988433660; called by muse, mutect2
- TADA3 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 15/217 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV99809648; called by muse, mutect2
- TCHH | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 77/618 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.092); catalogued as rs1252441898, COSV100914869, COSV100914889; called by muse, varscan2
- THAP6 | c.640G>C p.E214Q | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV61162623; called by muse, mutect2, varscan2
- THOC2 | c.1191-1G>C p.X397_splice | Splice Site (SNP) | VAF 7/62 reads (11%) | catalogued as COSV99834083; called by muse, varscan2
- TM9SF4 | c.735G>C p.E245D | Missense Mutation (SNP) | VAF 22/347 reads (6%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.568); catalogued as rs1212072638; called by muse, mutect2
- TM9SF4 | c.1757C>T p.A586V | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs764836180; called by muse, mutect2
- TP53 | c.631A>G p.T211A | Missense Mutation (SNP) | VAF 20/282 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as rs1060501198, COSV52688982, COSV52795736, COSV52991157; ClinVar: uncertain significance; called by muse, mutect2
- TRAV38-1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 45/258 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as rs1310878454; called by muse, mutect2, varscan2
- TRPV6 | c.148G>T p.G50W | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); catalogued as COSV63893006; called by muse, mutect2, varscan2
- TSHZ3 | c.2776G>T p.D926Y | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53668064, COSV99551324; called by muse, varscan2
- UNC13A | c.531G>A p.W177* | Nonsense Mutation (SNP) | VAF 10/156 reads (6%) | catalogued as COSV53213520; called by muse, mutect2
- USP35 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.033); catalogued as rs1367617217; called by mutect2, varscan2
- VIT | c.426G>C p.K142N | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.143); catalogued as COSV64896857; called by muse, mutect2
- VPS72 | c.235A>G p.R79G | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as rs1164717488; called by muse, mutect2
- WDR17 | c.1738G>T p.G580* | Nonsense Mutation (SNP) | VAF 16/98 reads (16%) | catalogued as COSV54585157; called by muse, mutect2, varscan2
- WDR35 | c.1088C>T p.T363M | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs200341288, COSV55602382; called by muse, mutect2, varscan2
- ZIC1 | c.208G>T p.G70C | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99291734; called by muse, mutect2
- ZNF423 | c.1222G>A p.D408N (on ENST00000563137 / NM_001379286.1; = p.D400N on NM_015069.4) | Missense Mutation (SNP) | VAF 44/334 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.017); catalogued as COSV52175732; called by muse, mutect2, varscan2
- ZNF560 | c.534G>A p.W178* | Nonsense Mutation (SNP) | VAF 10/108 reads (9%) | catalogued as COSV56865962; called by muse, mutect2
- ZNF676 | c.1663C>A p.H555N (on ENST00000650058; = p.H523N on NM_001001411.3) | Missense Mutation (SNP) | VAF 38/386 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1457320488; called by muse, mutect2
- ZNF716 | c.1256G>C p.C419S | Missense Mutation (SNP) | VAF 45/392 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as COSV101348539; called by muse, varscan2
- ZNF98 | c.1090C>A p.H364N | Missense Mutation (SNP) | VAF 20/331 reads (6%) | SIFT tolerated (0.65); PolyPhen benign (0.005); catalogued as COSV63339629; called by muse, mutect2
- ABCA8 | c.2420C>A p.A807E | Missense Mutation (SNP) | VAF 37/355 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- ABHD12 | c.788-1G>C p.X263_splice | Splice Site (SNP) | VAF 19/314 reads (6%) | called by muse, mutect2
- AC053503.6 | c.628G>C p.E210Q | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- ACIN1 | c.3576A>T p.K1192N | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- ACSS1 | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.026); called by muse, mutect2
- ADAMTSL4 | c.544G>C p.E182Q | Missense Mutation (SNP) | VAF 26/546 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.115); called by muse, mutect2
- ADCY10 | c.1121C>A p.S374Y | Missense Mutation (SNP) | VAF 34/476 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- AGBL3 | c.2074G>C p.D692H | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AHDC1 | c.664del p.A222Pfs*38 | Frame Shift Del (DEL) | VAF 10/57 reads (18%) | called by mutect2, pindel, varscan2
- AJUBA | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2
- AKAP14 | c.313A>T p.K105* | Nonsense Mutation (SNP) | VAF 22/147 reads (15%) | called by muse, mutect2, varscan2
- AKAP6 | c.3697G>A p.E1233K | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- ALPP | c.966C>A p.S322R | Missense Mutation (SNP) | VAF 48/508 reads (9%) | SIFT tolerated (0.66); PolyPhen benign (0.099); called by muse, mutect2
- ANKRD11 | c.2908G>A p.E970K | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ANKRD34A | c.980C>T p.S327L | Missense Mutation (SNP) | VAF 12/238 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- ANKRD45 | c.754G>T p.V252L | Missense Mutation (SNP) | VAF 86/365 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ANO3 | c.1609C>A p.H537N | Missense Mutation (SNP) | VAF 24/224 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ANP32B | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 12/221 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.848); called by muse, mutect2
- AQP12B | c.123+3G>T | Splice Region (SNP) | VAF 34/390 reads (9%) | called by muse, mutect2
- AR | c.2261C>A p.S754Y | Missense Mutation (SNP) | VAF 53/268 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARAP2 | c.3263+1G>T p.X1088_splice | Splice Site (SNP) | VAF 21/146 reads (14%) | called by muse, mutect2, varscan2
- ARGFX | c.208G>T p.A70S | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP44 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 12/227 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2
- ARMCX2 | c.1150G>T p.G384C | Missense Mutation (SNP) | VAF 39/274 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ASTN1 | c.2944T>A p.L982M | Missense Mutation (SNP) | VAF 63/231 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ASTN2 | c.1071G>T p.E357D | Missense Mutation (SNP) | VAF 23/196 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- ATMIN | c.1672G>C p.D558H | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- ATP11C | c.784+1G>C p.X262_splice | Splice Site (SNP) | VAF 19/141 reads (13%) | called by muse, mutect2, varscan2
- ATP6AP1 | c.496G>C p.E166Q | Missense Mutation (SNP) | VAF 32/181 reads (18%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- B3GALNT2 | c.1256C>G p.S419C | Missense Mutation (SNP) | VAF 15/284 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- BAZ2B | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- BCL9 | c.992C>G p.P331R | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.047); called by muse, mutect2
- BOC | c.-83G>T | Splice Region (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2, varscan2
- BTBD10 | c.675T>G p.F225L | Missense Mutation (SNP) | VAF 13/169 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.355); called by muse, mutect2
- C17orf67 | c.55G>T p.E19* | Nonsense Mutation (SNP) | VAF 23/107 reads (21%) | called by muse, mutect2, varscan2
- C2CD5 | c.579G>C p.Q193H | Missense Mutation (SNP) | VAF 27/424 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2
- C7orf25 | c.1142G>C p.R381T | Missense Mutation (SNP) | VAF 31/269 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CAD | c.4204G>T p.G1402C | Missense Mutation (SNP) | VAF 45/376 reads (12%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CARMIL1 | c.3327G>T p.K1109N | Missense Mutation (SNP) | VAF 74/210 reads (35%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC102B | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 59/319 reads (18%) | called by muse, mutect2, varscan2
- CDC40 | c.22C>G p.L8V | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); called by muse, mutect2
- CDH10 | c.1552C>G p.P518A | Missense Mutation (SNP) | VAF 13/169 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.495); called by muse, mutect2
- CFAP157 | c.990C>A p.S330R | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- CLIP1 | c.2613G>C p.Q871H (on ENST00000620786 / NM_001247997.1; = p.Q860H on NM_002956.2) | Missense Mutation (SNP) | VAF 10/197 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.62); called by muse, mutect2
- CLTC | c.1162C>G p.P388A | Missense Mutation (SNP) | VAF 18/205 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- CMYA5 | c.11888C>G p.S3963C | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.934); called by muse, mutect2
- CNDP1 | c.687C>G p.N229K | Missense Mutation (SNP) | VAF 40/324 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- COBLL1 | c.964A>T p.T322S (on ENST00000392717; = p.T284S on NM_014900.5) | Missense Mutation (SNP) | VAF 28/378 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL11A1 | c.3515C>A p.P1172H | Missense Mutation (SNP) | VAF 22/337 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- COL11A1 | c.2434C>A p.P812T | Missense Mutation (SNP) | VAF 34/478 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- COMMD4 | c.238G>T p.A80S | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- COPA | c.929A>T p.H310L | Missense Mutation (SNP) | VAF 13/182 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- CREB3L4 | c.242C>A p.S81* | Nonsense Mutation (SNP) | VAF 24/230 reads (10%) | called by muse, mutect2
- CROT | c.43C>T p.Q15* | Nonsense Mutation (SNP) | VAF 6/97 reads (6%) | called by muse, mutect2
- CSMD2 | c.8659G>T p.E2887* | Nonsense Mutation (SNP) | VAF 8/73 reads (11%) | called by muse, mutect2
- CSMD3 | c.3086G>T p.G1029V (on ENST00000297405 / NM_001363185.1; = p.G925V on NM_052900.3) | Missense Mutation (SNP) | VAF 56/323 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- DCAF12L2 | c.61G>T p.G21W | Missense Mutation (SNP) | VAF 70/377 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- DESI2 | c.523G>T p.A175S | Missense Mutation (SNP) | VAF 78/376 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.007); called by mutect2, varscan2
- DNAAF5 | c.816G>T p.W272C | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH8 | c.12871G>C p.E4291Q | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DPPA2 | c.557T>A p.L186* | Nonsense Mutation (SNP) | VAF 23/290 reads (8%) | called by muse, mutect2
- DRP2 | c.1750C>A p.L584M | Missense Mutation (SNP) | VAF 37/277 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- DYNC1I1 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 41/302 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- DYNC1I2 | c.1825G>A p.D609N | Missense Mutation (SNP) | VAF 13/235 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.367); called by muse, mutect2
- EFR3B | c.803A>T p.K268M | Missense Mutation (SNP) | VAF 29/305 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- EIF2S3B | c.679C>A p.Q227K | Missense Mutation (SNP) | VAF 45/326 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ELMO2 | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 27/219 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- EPX | c.820C>A p.R274S | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERBIN | c.802C>T p.L268F | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ESCO1 | c.1837dup p.R613Kfs*8 | Frame Shift Ins (INS) | VAF 12/69 reads (17%) | called by mutect2, pindel, varscan2
- EXOSC10 | c.331G>C p.D111H | Missense Mutation (SNP) | VAF 5/105 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- F5 | c.2645G>A p.W882* | Nonsense Mutation (SNP) | VAF 8/118 reads (7%) | called by muse, mutect2
- FAN1 | c.1523C>T p.S508L | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- FBN2 | c.5792T>G p.M1931R | Missense Mutation (SNP) | VAF 36/410 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.038); called by muse, mutect2
- FGF23 | c.218T>C p.L73P | Missense Mutation (SNP) | VAF 28/458 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- FHOD3 | c.3131C>G p.S1044C (on ENST00000359247 / NM_001281739.3; = p.S1061C on NM_025135.5) | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- FLG | c.11246C>A p.S3749* | Nonsense Mutation (SNP) | VAF 73/706 reads (10%) | called by muse, mutect2, varscan2
- FLG | c.5569G>C p.G1857R | Missense Mutation (SNP) | VAF 69/408 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FLNC | c.6851G>A p.G2284E | Missense Mutation (SNP) | VAF 50/283 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FMNL1 | c.2861A>T p.D954V | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- FPR1 | c.491T>C p.V164A | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.145); called by muse, mutect2
- FRG2C | c.667C>A p.Q223K | Missense Mutation (SNP) | VAF 28/674 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.828); called by muse, mutect2
- FRMD5 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 19/237 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.079); called by muse, mutect2
- FZD8 | c.289C>G p.L97V | Missense Mutation (SNP) | VAF 24/248 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); called by muse, mutect2
- GAK | c.3508+1G>T p.X1170_splice | Splice Site (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- GALNTL6 | c.752T>A p.L251Q | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GAS7 | c.1420A>T p.M474L (on ENST00000432992 / NM_201433.2; = p.M334L on NM_003644.3) | Missense Mutation (SNP) | VAF 13/174 reads (7%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2
- GOLGB1 | c.6181G>T p.E2061* | Nonsense Mutation (SNP) | VAF 8/114 reads (7%) | called by muse, mutect2
- GREB1 | c.2872C>G p.P958A | Missense Mutation (SNP) | VAF 27/359 reads (8%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.879); called by muse, mutect2
- GSDME | c.100C>G p.L34V | Missense Mutation (SNP) | VAF 52/431 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GUCY1A2 | c.960C>G p.I320M | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- H1-4 | c.222G>C p.E74D | Missense Mutation (SNP) | VAF 17/250 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.238); called by muse, mutect2
- HAP1 | c.1847G>T p.G616V (on ENST00000310778 / NM_001367460.1; = p.G564V on NM_177977.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2
- HCFC2 | c.1093C>G p.L365V | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2
- HGH1 | c.999G>T p.K333N | Missense Mutation (SNP) | VAF 34/456 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.041); called by muse, mutect2
- HID1 | c.904C>G p.P302A | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HIF3A | c.926G>T p.R309L (on ENST00000377670 / NM_152795.4; = p.R240L on NM_022462.4) | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- HOXA10 | c.700C>A p.Q234K | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.93); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HOXB7 | c.492del p.R165Gfs*26 | Frame Shift Del (DEL) | VAF 32/280 reads (11%) | called by mutect2, varscan2
- IFT140 | c.1764dup p.S589Qfs*4 | Frame Shift Ins (INS) | VAF 25/130 reads (19%) | called by mutect2, pindel, varscan2
- IGF2BP1 | c.950A>G p.D317G | Missense Mutation (SNP) | VAF 36/227 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- IGHG4 | c.179C>G p.S60* | Nonsense Mutation (SNP) | VAF 30/676 reads (4%) | called by muse, mutect2
- IGHV1-3 | c.252G>T p.Q84H | Missense Mutation (SNP) | VAF 93/588 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- IL17RA | c.2173G>T p.D725Y | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- INSC | c.1207G>T p.D403Y | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- ITGA4 | c.1212T>A p.N404K | Missense Mutation (SNP) | VAF 12/241 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KDM5A | c.3549G>A p.W1183* | Nonsense Mutation (SNP) | VAF 25/389 reads (6%) | called by muse, mutect2
- KIAA0825 | c.3406G>T p.G1136C | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KIF4A | c.2162A>T p.Q721L | Missense Mutation (SNP) | VAF 49/312 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- KLHL23 | c.860C>G p.S287* | Nonsense Mutation (SNP) | VAF 24/212 reads (11%) | called by muse, mutect2, varscan2
- KLHL35 | c.1494G>C p.M498I | Missense Mutation (SNP) | VAF 19/211 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.748); called by muse, mutect2
- KRTAP29-1 | c.955G>A p.G319S | Missense Mutation (SNP) | VAF 36/247 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- L1CAM | c.427G>T p.V143L | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- LCT | c.5623C>T p.L1875F | Missense Mutation (SNP) | VAF 28/239 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- LHFPL5 | c.360C>G p.I120M | Missense Mutation (SNP) | VAF 19/316 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.044); called by muse, mutect2
- LNPEP | c.2782A>G p.I928V | Missense Mutation (SNP) | VAF 28/215 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- LOXL4 | c.1387T>G p.C463G | Missense Mutation (SNP) | VAF 26/392 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- LPCAT4 | c.1075G>C p.E359Q | Missense Mutation (SNP) | VAF 27/328 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.086); called by muse, mutect2
- LRRC10 | c.221T>C p.L74P | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC37B | c.1061C>T p.S354L | Missense Mutation (SNP) | VAF 29/427 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.018); called by muse, mutect2
- MAGEB17 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.7); called by muse, varscan2
- MAT2A | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- MDFIC | c.446G>A p.S149N | Missense Mutation (SNP) | VAF 45/210 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- MED13L | c.5367G>T p.R1789= | Splice Region (SNP) | VAF 18/302 reads (6%) | called by muse, mutect2
- MINDY4B | c.1317G>T p.E439D | Missense Mutation (SNP) | VAF 14/308 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- MRC1 | c.179G>T p.W60L | Missense Mutation (SNP) | VAF 116/671 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MRC1 | c.180G>T p.W60C | Missense Mutation (SNP) | VAF 114/663 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MROH2A | c.3127G>C p.E1043Q | Missense Mutation (SNP) | VAF 23/253 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.259); called by muse, mutect2
- MSANTD1 | c.787G>T p.E263* | Nonsense Mutation (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- MYH8 | c.1009-1G>T p.X337_splice | Splice Site (SNP) | VAF 49/361 reads (14%) | called by muse, mutect2, varscan2
- MYOZ2 | c.672T>A p.N224K | Missense Mutation (SNP) | VAF 41/280 reads (15%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- NCR3LG1 | c.184G>T p.G62C | Missense Mutation (SNP) | VAF 14/278 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NOS3 | c.904C>A p.L302I | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- NUTM2D | c.1793A>T p.E598V | Missense Mutation (SNP) | VAF 34/950 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- OAS1 | c.721G>T p.E241* | Nonsense Mutation (SNP) | VAF 57/348 reads (16%) | called by muse, mutect2, varscan2
- OBSCN | c.17648T>A p.M5883K | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- OGA | c.392T>C p.I131T | Missense Mutation (SNP) | VAF 17/242 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2
- OR10A5 | c.226C>G p.L76V | Missense Mutation (SNP) | VAF 26/502 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.2); called by muse, mutect2
- OR2A25 | c.481T>A p.L161I | Missense Mutation (SNP) | VAF 49/330 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR2AJ1 | c.432G>T p.M144I | Missense Mutation (SNP) | VAF 33/274 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- OR2F1 | c.640G>T p.V214F | Missense Mutation (SNP) | VAF 34/244 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2M5 | c.920A>T p.K307M | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- OR4C16 | c.730G>T p.V244L | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.232); called by muse, mutect2
- OR56A1 | c.887G>C p.G296A | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.905); called by muse, mutect2
- OR8K3 | c.828T>A p.F276L | Missense Mutation (SNP) | VAF 35/289 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- PCDH19 | c.1420T>G p.S474A | Missense Mutation (SNP) | VAF 22/201 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PCDHB5 | c.1393C>A p.P465T | Missense Mutation (SNP) | VAF 102/731 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCK1 | c.229T>A p.L77M | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, varscan2
- PCK1 | c.367G>C p.E123Q | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.006); called by muse, varscan2
- PHF8 | c.1621G>C p.E541Q (on ENST00000357988 / NM_001184896.1; = p.E505Q on NM_015107.3) | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.173); called by muse, mutect2
- PI4K2B | c.503A>T p.K168M | Missense Mutation (SNP) | VAF 48/666 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PIGA | c.1265C>T p.P422L | Missense Mutation (SNP) | VAF 30/262 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- PIK3CA | c.1873G>C p.D625H | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PKHD1L1 | c.3508G>C p.G1170R | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLA2G4A | c.2075G>T p.R692I | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- PLOD2 | c.1501-7C>A | Splice Region (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- PLTP | c.903G>A p.M301I | Missense Mutation (SNP) | VAF 44/327 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PNKP | c.152-3C>T | Splice Region (SNP) | VAF 32/375 reads (9%) | called by muse, mutect2
- PNLIPRP2 | c.586C>A p.P196T | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- PNLIPRP2 | c.587C>A p.P196Q | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PPFIA3 | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.122); called by muse, mutect2
- PRSS33 | c.380T>A p.L127Q | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- PRSS38 | c.646C>A p.L216M | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- PRSS58 | c.7T>A p.F3I | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2
- PSAP | c.1506G>T p.W502C | Missense Mutation (SNP) | VAF 64/452 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTH | c.92G>C p.R31T | Missense Mutation (SNP) | VAF 33/320 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPRQ | c.3095C>T p.S1032L (on ENST00000616559; = p.S990L on NM_001145026.2) | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- RAB40A | c.788dup p.S264Efs*47 | Frame Shift Ins (INS) | VAF 50/318 reads (16%) | called by mutect2, varscan2
- RANBP2 | c.8663A>C p.Q2888P | Missense Mutation (SNP) | VAF 24/251 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2
- RBM20 | c.2726T>A p.V909E | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- RCVRN | c.558C>G p.I186M | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- REG3A | c.204C>A p.C68* | Nonsense Mutation (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
- RELN | c.6982A>G p.T2328A | Missense Mutation (SNP) | VAF 86/453 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RELN | c.3020C>T p.T1007I | Missense Mutation (SNP) | VAF 98/642 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RIMS2 | c.2954G>A p.R985K (on ENST00000666250 / NM_001348490.2; = p.R793K on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 72/270 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- RNF167 | c.787C>T p.Q263* | Nonsense Mutation (SNP) | VAF 10/108 reads (9%) | called by muse, mutect2
- RNF223 | c.397G>T p.E133* | Nonsense Mutation (SNP) | VAF 14/90 reads (16%) | called by muse, mutect2, varscan2
- RXRB | c.1332C>G p.I444M | Missense Mutation (SNP) | VAF 42/232 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- RYR2 | c.4676G>A p.R1559K | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.83); PolyPhen benign (0.02); called by muse, mutect2
- SCAF4 | c.514A>T p.N172Y | Missense Mutation (SNP) | VAF 112/461 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SCARF1 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT tolerated (0.74); PolyPhen benign (0.007); called by muse, mutect2
- SCN1A | c.1710C>A p.S570R | Missense Mutation (SNP) | VAF 15/218 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); called by muse, mutect2
- SCN3A | c.725A>G p.Q242R | Missense Mutation (SNP) | VAF 24/308 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); called by muse, mutect2
- SCN7A | c.3676T>C p.Y1226H | Missense Mutation (SNP) | VAF 16/171 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); called by muse, mutect2
- SERPINA4 | c.186C>G p.F62L | Missense Mutation (SNP) | VAF 7/192 reads (4%) | SIFT tolerated (0.7); PolyPhen benign (0.012); called by muse, mutect2
- SI | c.785C>A p.T262N | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- SLC12A4 | c.1405A>T p.S469C | Missense Mutation (SNP) | VAF 26/254 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0.007); called by muse, mutect2
- SLC25A1 | c.456C>G p.H152Q | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- SLC26A11 | c.147G>T p.K49N | Missense Mutation (SNP) | VAF 35/277 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- SLC7A1 | c.433G>T p.G145W | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- SLIT2 | c.3038G>T p.C1013F | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLITRK5 | c.665A>C p.Q222P | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.425); called by muse, mutect2
- SMARCA1 | c.2243C>A p.P748H | Missense Mutation (SNP) | VAF 45/425 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SNX20 | c.787C>A p.H263N | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- SORBS2 | c.833G>T p.S278I (on ENST00000284776 / NM_021069.5; = p.S371I on NM_003603.6) | Missense Mutation (SNP) | VAF 50/363 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- SPOCK1 | c.1021G>T p.G341C | Missense Mutation (SNP) | VAF 37/241 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SRGAP3 | c.1557A>G p.I519M | Missense Mutation (SNP) | VAF 37/353 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SRPK1 | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 24/287 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.447); called by muse, mutect2
- SRRM2 | c.2212C>G p.Q738E | Missense Mutation (SNP) | VAF 33/256 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- STAM2 | c.1409C>G p.S470* | Nonsense Mutation (SNP) | VAF 16/359 reads (4%) | called by muse, mutect2
- STX1A | c.342G>C p.R114S | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- STX4 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 20/225 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- STYXL2 | c.3353C>A p.S1118Y | Missense Mutation (SNP) | VAF 30/456 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.312); called by muse, mutect2
- SUPT16H | c.1795A>T p.T599S | Missense Mutation (SNP) | VAF 42/272 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- SYMPK | c.2062G>T p.D688Y | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); called by muse, mutect2
- SYNE2 | c.16166C>T p.A5389V | Missense Mutation (SNP) | VAF 76/452 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- TAOK1 | c.1238G>C p.R413T | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2
- TASOR | c.3289G>A p.E1097K (on ENST00000355628 / NM_001365636.2; = p.E721K on NM_015224.3) | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0.003); called by muse, mutect2
- TBC1D10C | c.762G>T p.E254D | Missense Mutation (SNP) | VAF 12/236 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.405); called by muse, mutect2
- TDRD9 | c.3562C>A p.P1188T | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2
- TENT4B | c.260G>T p.G87V (on ENST00000561678 / NM_001365323.2; = p.G72V on NM_001040284.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.815); called by muse, mutect2
- TEP1 | c.5911G>T p.A1971S | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- TET1 | c.241C>A p.R81S | Missense Mutation (SNP) | VAF 16/179 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); called by muse, mutect2
- TMEM131 | c.4528G>A p.A1510T | Missense Mutation (SNP) | VAF 22/249 reads (9%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); called by muse, mutect2
- TMEM132C | c.2368G>A p.V790M | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.409); called by muse, mutect2
- TMEM156 | c.261C>A p.C87* | Nonsense Mutation (SNP) | VAF 28/415 reads (7%) | called by muse, mutect2
- TMEM41B | c.250G>A p.V84M | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, varscan2
- TPTE | c.1181T>A p.V394D (on ENST00000618007 / NM_199261.4; = p.V376D on NM_199259.4) | Missense Mutation (SNP) | VAF 9/149 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- TRIM49 | c.46C>A p.P16T | Missense Mutation (SNP) | VAF 38/184 reads (21%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.506); called by mutect2, varscan2
- TRIM51 | c.1021T>A p.Y341N | Missense Mutation (SNP) | VAF 53/437 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.47); called by muse, mutect2, varscan2
- TRIO | c.6201G>T p.K2067N | Missense Mutation (SNP) | VAF 23/209 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRIT1 | c.924del p.G310Vfs*5 | Frame Shift Del (DEL) | VAF 16/137 reads (12%) | called by mutect2, pindel, varscan2
- TSNAX | c.71G>T p.R24I | Missense Mutation (SNP) | VAF 17/190 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.231); called by muse, mutect2
- UBAP2L | c.2755G>T p.G919C | Missense Mutation (SNP) | VAF 30/212 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UNC5B | c.2123T>A p.L708Q | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- VCAN | c.1129A>T p.R377* | Nonsense Mutation (SNP) | VAF 15/113 reads (13%) | called by muse, mutect2, varscan2
- VCPIP1 | c.2488C>T p.Q830* | Nonsense Mutation (SNP) | VAF 26/86 reads (30%) | called by muse, mutect2, varscan2
- VPS13A | c.5145G>T p.L1715F | Missense Mutation (SNP) | VAF 24/260 reads (9%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.851); called by muse, mutect2
- WNT16 | c.663C>A p.C221* (on ENST00000222462 / NM_057168.2; = p.C211* on NM_016087.2) | Nonsense Mutation (SNP) | VAF 12/85 reads (14%) | called by muse, mutect2, varscan2
- ZBTB14 | c.730G>T p.G244W | Missense Mutation (SNP) | VAF 28/276 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- ZBTB33 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 56/433 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- ZBTB38 | c.2802G>A p.M934I | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- ZBTB49 | c.2237G>T p.S746I | Missense Mutation (SNP) | VAF 28/404 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZFHX4 | c.6089C>A p.T2030K | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.067); called by muse, varscan2
- ZG16B | c.344C>A p.P115Q | Missense Mutation (SNP) | VAF 24/173 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- ZIC5 | c.698C>G p.P233R | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ZNF429 | c.1330A>T p.K444* | Nonsense Mutation (SNP) | VAF 14/170 reads (8%) | called by muse, mutect2
- ZNF565 | c.79G>C p.E27Q | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.413); called by muse, mutect2
- ZNF566 | c.591G>T p.K197N | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF695 | c.925C>A p.P309T | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ZNF729 | c.1601A>G p.H534R | Missense Mutation (SNP) | VAF 27/269 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZNF99 | c.739T>C p.C247R | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCC11 | c.3192C>T p.F1064= | Silent (SNP) | VAF 32/189 reads (17%) | catalogued as rs145424602; called by muse, mutect2, varscan2
- ADAD1 | c.60G>A p.L20= | Silent (SNP) | VAF 28/194 reads (14%) | called by muse, mutect2, varscan2
- ADAM22 | c.1278G>C p.L426= | Silent (SNP) | VAF 18/165 reads (11%) | called by muse, mutect2, varscan2
- ADGRG4 | c.7620G>T p.L2540= | Silent (SNP) | VAF 16/326 reads (5%) | called by muse, mutect2
- ADGRL2 | c.4044T>C p.T1348= (on ENST00000370717 / NM_001366005.1; = p.T1292= on NM_012302.4) | Silent (SNP) | VAF 18/235 reads (8%) | called by muse, mutect2
- AJUBA | c.396G>A p.A132= | Silent (SNP) | VAF 29/129 reads (22%) | catalogued as rs1319296765; called by muse, mutect2, varscan2
- AMHR2 | c.177C>A p.R59= | Silent (SNP) | VAF 18/178 reads (10%) | called by muse, mutect2, varscan2
- AMZ2 | c.66T>A p.L22= | Silent (SNP) | VAF 25/265 reads (9%) | called by muse, mutect2, varscan2
- ANK2 | c.8136T>A p.P2712= | Silent (SNP) | VAF 60/300 reads (20%) | called by muse, mutect2, varscan2
- APOB | c.2409C>A p.A803= | Silent (SNP) | VAF 10/96 reads (10%) | called by muse, mutect2, varscan2
- ARMC5 | c.12G>A p.A4= | Silent (SNP) | VAF 16/317 reads (5%) | catalogued as rs1339700834, COSV51655424; called by muse, mutect2
- ARSH | c.639T>C p.S213= | Silent (SNP) | VAF 72/466 reads (15%) | catalogued as COSV66963588; called by muse, mutect2, varscan2
- ASB14 | c.370T>C p.L124= (on ENST00000389601; = p.L123= on NM_001142733.3) | Silent (SNP) | VAF 42/265 reads (16%) | called by muse, mutect2, varscan2
- ASXL2 | c.2613A>G p.S871= | Silent (SNP) | VAF 20/232 reads (9%) | called by muse, mutect2
- ATP12A | c.1041G>T p.V347= | Silent (SNP) | VAF 12/59 reads (20%) | called by muse, mutect2, varscan2
- BRINP3 | c.2085C>G p.S695= | Silent (SNP) | VAF 13/152 reads (9%) | catalogued as rs970240592; called by muse, mutect2
- BTNL3 | c.333G>C p.L111= | Silent (SNP) | VAF 39/359 reads (11%) | called by muse, mutect2, varscan2
- C7 | c.1950A>T p.T650= | Silent (SNP) | VAF 28/290 reads (10%) | called by muse, mutect2
- CABP2 | c.201C>G p.A67= | Silent (SNP) | VAF 26/175 reads (15%) | called by muse, mutect2, varscan2
- CACNA1H | c.1650G>T p.L550= | Silent (SNP) | VAF 10/93 reads (11%) | catalogued as rs1227922346; called by muse, mutect2, varscan2
- CBLC | c.162G>A p.L54= | Silent (SNP) | VAF 12/142 reads (8%) | called by muse, mutect2
- CCNA1 | c.1182G>C p.L394= | Silent (SNP) | VAF 9/76 reads (12%) | called by muse, mutect2, varscan2
- CD163 | c.522C>T p.I174= | Silent (SNP) | VAF 21/117 reads (18%) | catalogued as COSV63137863; called by muse, mutect2, varscan2
- CD19 | c.588C>A p.L196= | Silent (SNP) | VAF 26/304 reads (9%) | called by muse, mutect2
- CDC42EP3 | c.273G>T p.S91= | Silent (SNP) | VAF 11/99 reads (11%) | catalogued as COSV99767718; called by muse, mutect2, varscan2
- CLCA4 | c.1155C>T p.I385= | Silent (SNP) | VAF 4/78 reads (5%) | called by muse, mutect2
- CLDN17 | c.411G>A p.V137= | Silent (SNP) | VAF 14/269 reads (5%) | catalogued as COSV54522874; called by muse, mutect2
- COMMD4 | c.237G>T p.A79= | Silent (SNP) | VAF 22/178 reads (12%) | catalogued as rs139615169, COSV51190499; called by muse, mutect2, varscan2
- CPEB4 | c.789T>C p.H263= | Silent (SNP) | VAF 8/135 reads (6%) | catalogued as rs921927280; called by muse, mutect2
- CPZ | c.987G>T p.T329= (on ENST00000360986 / NM_001014447.3; = p.T318= on NM_003652.3) | Silent (SNP) | VAF 20/254 reads (8%) | catalogued as rs371225755; called by muse, mutect2
- CSE1L | c.2841G>A p.V947= | Silent (SNP) | VAF 18/250 reads (7%) | catalogued as COSV53700354; called by muse, mutect2
- CTNND2 | c.912C>A p.P304= | Silent (SNP) | VAF 36/332 reads (11%) | called by muse, mutect2, varscan2
- CTSA | c.1245C>T p.L415= | Silent (SNP) | VAF 26/179 reads (15%) | called by muse, mutect2, varscan2
- CYB5R3 | c.211C>T p.L71= | Silent (SNP) | VAF 19/129 reads (15%) | called by muse, mutect2, varscan2
- CYSLTR2 | c.714G>T p.L238= | Silent (SNP) | VAF 36/211 reads (17%) | called by muse, mutect2, varscan2
- DAPP1 | c.429G>T p.R143= | Silent (SNP) | VAF 13/270 reads (5%) | catalogued as COSV56453059; called by muse, mutect2
- DCAF4 | c.168C>T p.G56= | Silent (SNP) | VAF 16/144 reads (11%) | catalogued as rs1004038587; called by muse, varscan2
- DCT | c.609C>A p.P203= | Silent (SNP) | VAF 25/148 reads (17%) | catalogued as rs12876972, COSV65469770; called by muse, mutect2, varscan2
- DCUN1D4 | c.726A>T p.S242= (on ENST00000334635 / NM_001287757.1; = p.S207= on NM_015115.3) | Silent (SNP) | VAF 22/107 reads (21%) | called by muse, mutect2, varscan2
- DDR2 | c.2226G>T p.R742= | Silent (SNP) | VAF 32/336 reads (10%) | called by muse, mutect2
- DPP9 | c.147C>T p.V49= (on ENST00000598800; = p.V78= on NM_139159.5) | Silent (SNP) | VAF 10/201 reads (5%) | catalogued as rs1347762231, COSV99505667; called by muse, mutect2
- EGFLAM | c.2254C>T p.L752= | Silent (SNP) | VAF 22/266 reads (8%) | called by muse, mutect2
- EIF4G3 | c.4524G>T p.L1508= | Silent (SNP) | VAF 9/122 reads (7%) | called by muse, mutect2
- ERVV-2 | c.591A>G p.L197= | Silent (SNP) | VAF 38/396 reads (10%) | called by muse, mutect2, varscan2
- EZR | c.1524C>T p.I508= | Silent (SNP) | VAF 22/167 reads (13%) | catalogued as COSV51911082; called by muse, mutect2, varscan2
- FAM189A1 | c.459C>T p.L153= | Silent (SNP) | VAF 32/195 reads (16%) | catalogued as rs1055299151; called by muse, mutect2, varscan2
- FBXO47 | c.96C>A p.G32= | Silent (SNP) | VAF 16/214 reads (7%) | catalogued as rs367616216; called by muse, mutect2
- FN3K | c.231C>T p.I77= | Silent (SNP) | VAF 17/198 reads (9%) | catalogued as rs745338444; called by muse, mutect2
- FSIP2 | c.1869C>A p.I623= | Silent (SNP) | VAF 15/132 reads (11%) | called by muse, mutect2, varscan2
- GAB2 | c.804C>T p.L268= (on ENST00000361507 / NM_080491.3; = p.L230= on NM_012296.3) | Silent (SNP) | VAF 43/441 reads (10%) | catalogued as rs768623949, COSV60871714; called by muse, mutect2
- GALNT9 | c.192G>T p.L64= | Silent (SNP) | VAF 19/130 reads (15%) | called by muse, mutect2, varscan2
- GFUS | c.720C>T p.I240= | Silent (SNP) | VAF 28/212 reads (13%) | catalogued as rs1201951552; called by muse, mutect2, varscan2
- GREB1 | c.2727C>T p.A909= | Silent (SNP) | VAF 19/123 reads (15%) | catalogued as rs555615375; called by mutect2, varscan2
- HNRNPF | c.339G>T p.V113= | Silent (SNP) | VAF 17/115 reads (15%) | called by muse, mutect2, varscan2
- KCNMB4 | c.564G>T p.V188= | Silent (SNP) | VAF 30/185 reads (16%) | called by muse, mutect2, varscan2
- KDM5B | c.537C>T p.L179= | Silent (SNP) | VAF 15/211 reads (7%) | called by muse, mutect2
- KIF27 | c.2808G>C p.L936= | Silent (SNP) | VAF 16/168 reads (10%) | called by muse, mutect2
- LMO7 | c.3123G>T p.G1041= (on ENST00000357063; = p.G722= on NM_005358.5) | Silent (SNP) | VAF 30/350 reads (9%) | called by muse, mutect2
- LOXHD1 | c.1959C>T p.F653= | Silent (SNP) | VAF 11/60 reads (18%) | called by muse, mutect2, varscan2
- LRP6 | c.1875G>A p.K625= | Silent (SNP) | VAF 29/193 reads (15%) | called by muse, mutect2, varscan2
- MAB21L3 | c.438C>T p.F146= | Silent (SNP) | VAF 10/146 reads (7%) | called by muse, mutect2
- MAGEB1 | c.780G>T p.V260= | Silent (SNP) | VAF 49/277 reads (18%) | catalogued as COSV100975046; called by muse, mutect2, varscan2
- MARK1 | c.27G>T p.T9= | Silent (SNP) | VAF 17/137 reads (12%) | catalogued as COSV100857032, COSV65070284; called by muse, mutect2, varscan2
- MTCL1 | c.4911G>T p.G1637= (on ENST00000306329 / NM_001378206.1; = p.G1318= on NM_015210.4) | Silent (SNP) | VAF 9/44 reads (20%) | called by muse, mutect2, varscan2
- MUC16 | c.4158C>T p.I1386= | Silent (SNP) | VAF 8/144 reads (6%) | catalogued as COSV101202220, COSV67441922; called by muse, mutect2
- MUC17 | c.7125C>T p.A2375= | Silent (SNP) | VAF 17/180 reads (9%) | catalogued as rs189420932, COSV60288934; called by muse, mutect2
- MYO1B | c.2352G>T p.T784= | Silent (SNP) | VAF 44/502 reads (9%) | called by muse, mutect2
- MYO7B | c.240C>A p.G80= | Silent (SNP) | VAF 13/166 reads (8%) | called by muse, mutect2
- NBAS | c.4152A>G p.S1384= | Silent (SNP) | VAF 17/314 reads (5%) | called by muse, mutect2
- NDST3 | c.2394T>A p.A798= | Silent (SNP) | VAF 20/92 reads (22%) | called by muse, mutect2, varscan2
- NHLRC2 | c.1308G>A p.V436= | Silent (SNP) | VAF 23/376 reads (6%) | called by muse, mutect2
- NOC3L | c.1752C>G p.L584= | Silent (SNP) | VAF 7/112 reads (6%) | called by muse, mutect2
- OAS2 | c.1278C>T p.N426= | Silent (SNP) | VAF 24/400 reads (6%) | catalogued as rs762942728; called by muse, mutect2
- OR11H4 | c.423G>A p.Q141= | Silent (SNP) | VAF 35/229 reads (15%) | called by muse, mutect2, varscan2
- OR2M7 | c.525C>A p.A175= | Silent (SNP) | VAF 55/340 reads (16%) | catalogued as COSV100522747; called by muse, mutect2, varscan2
- OR2T11 | c.678C>A p.P226= | Silent (SNP) | VAF 45/285 reads (16%) | called by muse, mutect2, varscan2
- OR52N2 | c.180C>A p.P60= | Silent (SNP) | VAF 8/79 reads (10%) | called by muse, mutect2, varscan2
- OR6B2 | c.102C>A p.T34= | Silent (SNP) | VAF 22/380 reads (6%) | catalogued as rs1390315526, COSV53152433; called by muse, mutect2
- OR6C70 | c.6G>A p.K2= | Silent (SNP) | VAF 3/20 reads (15%) | called by muse, mutect2
- OR6F1 | c.189G>C p.L63= | Silent (SNP) | VAF 16/198 reads (8%) | catalogued as COSV100128987; called by muse, mutect2
- PCDHB10 | c.270G>T p.L90= | Silent (SNP) | VAF 25/295 reads (8%) | called by muse, mutect2, varscan2
- PCDHGA7 | c.1701C>A p.L567= | Silent (SNP) | VAF 29/225 reads (13%) | catalogued as COSV99535822; called by muse, mutect2, varscan2
- PCDHGC3 | c.2235C>T p.D745= | Silent (SNP) | VAF 29/195 reads (15%) | called by muse, mutect2, varscan2
- PIK3CG | c.1890C>T p.L630= | Silent (SNP) | VAF 30/220 reads (14%) | catalogued as COSV100782750; called by muse, mutect2, varscan2
- PKHD1 | c.10092G>T p.L3364= | Silent (SNP) | VAF 97/310 reads (31%) | called by muse, mutect2, varscan2
- PLK1 | c.1650G>T p.V550= | Silent (SNP) | VAF 19/142 reads (13%) | called by muse, mutect2, varscan2
- POLA2 | c.573C>T p.I191= | Silent (SNP) | VAF 22/279 reads (8%) | called by muse, mutect2
- POLR1G | c.249C>T p.L83= | Silent (SNP) | VAF 10/110 reads (9%) | called by muse, mutect2
- POSTN | c.1155G>T p.T385= | Silent (SNP) | VAF 38/257 reads (15%) | catalogued as COSV101123526; called by muse, mutect2, varscan2
- PRKAG2 | c.477C>T p.L159= | Silent (SNP) | VAF 42/467 reads (9%) | catalogued as COSV99835596; called by muse, mutect2
- PROX1 | c.1116G>C p.S372= | Silent (SNP) | VAF 8/136 reads (6%) | catalogued as COSV54782344; called by muse, mutect2
- PTBP3 | c.1116A>T p.P372= | Silent (SNP) | VAF 7/62 reads (11%) | called by muse, varscan2
- PTCH1 | c.1992C>T p.L664= | Silent (SNP) | VAF 52/331 reads (16%) | catalogued as COSV59501850; called by muse, mutect2, varscan2
- PTPRN2 | c.1239A>T p.G413= | Silent (SNP) | VAF 15/97 reads (15%) | called by muse, mutect2, varscan2
- PTPRS | c.1473G>C p.L491= | Silent (SNP) | VAF 8/126 reads (6%) | called by muse, mutect2
- RNF212 | c.744C>T p.T248= (on ENST00000433731 / NM_001366918.1; = p.Q231* on NM_194439.4) | Silent (SNP) | VAF 47/431 reads (11%) | called by muse, mutect2, varscan2
- RSPH14 | c.783C>T p.I261= | Silent (SNP) | VAF 7/158 reads (4%) | catalogued as COSV53271293; called by muse, mutect2
- SEC23B | c.819T>A p.A273= | Silent (SNP) | VAF 39/361 reads (11%) | catalogued as COSV52721775; called by muse, mutect2, varscan2
- SETD1A | c.699G>T p.A233= | Silent (SNP) | VAF 24/288 reads (8%) | catalogued as rs145879879; called by muse, mutect2
- SLC12A4 | c.519C>T p.A173= | Silent (SNP) | VAF 26/181 reads (14%) | catalogued as rs1178474636; called by muse, mutect2, varscan2
- SLC17A6 | c.1092T>A p.P364= | Silent (SNP) | VAF 11/70 reads (16%) | called by muse, mutect2, varscan2
- SLC45A1 | c.318G>T p.A106= | Silent (SNP) | VAF 16/138 reads (12%) | catalogued as rs751344756, COSV57094250; called by muse, mutect2, varscan2
- SPTB | c.3810G>A p.L1270= | Silent (SNP) | VAF 58/396 reads (15%) | catalogued as COSV101072226; called by muse, mutect2, varscan2
- STK40 | c.531C>T p.I177= | Silent (SNP) | VAF 22/230 reads (10%) | called by muse, mutect2
- SULT1B1 | c.417A>G p.S139= | Silent (SNP) | VAF 45/270 reads (17%) | catalogued as rs536777076; called by muse, mutect2, varscan2
- TIE1 | c.2961C>A p.V987= | Silent (SNP) | VAF 28/268 reads (10%) | called by muse, mutect2, varscan2
- TLE6 | c.93G>A p.L31= | Silent (SNP) | VAF 14/172 reads (8%) | called by muse, mutect2
- TONSL | c.3759G>C p.L1253= | Silent (SNP) | VAF 11/157 reads (7%) | called by muse, mutect2
- TRAV13-1 | c.192G>A p.Q64= | Silent (SNP) | VAF 45/373 reads (12%) | called by muse, mutect2
- TRHDE | c.171C>G p.L57= | Silent (SNP) | VAF 14/275 reads (5%) | catalogued as COSV53860628; called by muse, mutect2
- TRIM51 | c.1020A>G p.K340= | Silent (SNP) | VAF 53/439 reads (12%) | called by muse, mutect2, varscan2
- TRO | c.2133C>A p.A711= | Silent (SNP) | VAF 22/187 reads (12%) | called by muse, mutect2, varscan2
- TSC22D2 | c.204C>G p.S68= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs539836261, COSV100721191; called by muse, mutect2, varscan2
- TTC34 | c.2184G>T p.L728= | Silent (SNP) | VAF 11/81 reads (14%) | called by muse, mutect2, varscan2
- TUBA4B | c.324C>T p.F108= | Silent (SNP) | VAF 14/157 reads (9%) | catalogued as COSV67524816; called by muse, mutect2
- UNC13A | c.402T>A p.P134= | Silent (SNP) | VAF 16/204 reads (8%) | called by muse, mutect2
- WAC | c.732G>T p.T244= | Silent (SNP) | VAF 38/568 reads (7%) | catalogued as COSV61567343; called by muse, mutect2
- WNK4 | c.2439T>A p.P813= | Silent (SNP) | VAF 12/104 reads (12%) | called by muse, varscan2
- XPNPEP2 | c.1836G>A p.Q612= | Silent (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2, varscan2
- ZIM2 | c.1513C>A p.R505= | Silent (SNP) | VAF 21/189 reads (11%) | catalogued as COSV99689256; called by muse, mutect2
- ZNF208 | c.3708G>T p.T1236= | Silent (SNP) | VAF 32/385 reads (8%) | catalogued as rs368192167; called by muse, mutect2
- ZNF219 | c.975C>T p.A325= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs751094498; called by muse, mutect2, varscan2
- ZNF410 | c.720C>G p.L240= | Silent (SNP) | VAF 12/170 reads (7%) | catalogued as COSV57912553; called by muse, mutect2
- ZNF680 | c.153C>T p.F51= | Silent (SNP) | VAF 28/254 reads (11%) | called by muse, mutect2, varscan2
- AC116655.1 | n.600T>C | RNA (SNP) | VAF 41/365 reads (11%) | called by muse, mutect2, varscan2
- AC122719.2 | n.136G>T | RNA (SNP) | VAF 24/326 reads (7%) | called by muse, mutect2
- AC133561.1 | n.1477C>A | RNA (SNP) | VAF 11/171 reads (6%) | called by muse, mutect2
- AMN1 | c.171+210T>A | Intron (SNP) | VAF 7/77 reads (9%) | called by muse, mutect2
- AMPH | c.1182+334G>T | Intron (SNP) | VAF 19/116 reads (16%) | called by muse, mutect2, varscan2
- ARHGAP26 | c.2356+2181A>G | Intron (SNP) | VAF 42/380 reads (11%) | called by muse, mutect2
- ARMCX4 | c.1038+1893G>A | Intron (SNP) | VAF 42/303 reads (14%) | called by muse, mutect2, varscan2
- BRCA2 | c.9502-902G>A | Intron (SNP) | VAF 10/82 reads (12%) | catalogued as rs1430555491; called by muse, mutect2, varscan2
- BSCL2 | chr11:62709504 G>A | 5'Flank (SNP) | VAF 16/154 reads (10%) | catalogued as rs992197695; called by muse, varscan2
- C10orf143 | c.69+2402G>T | Intron (SNP) | VAF 38/344 reads (11%) | called by muse, mutect2, varscan2
- C5orf17 | n.339C>A | RNA (SNP) | VAF 9/39 reads (23%) | called by muse, mutect2, varscan2
- C8orf87 | n.270G>T | RNA (SNP) | VAF 42/684 reads (6%) | called by muse, mutect2
- CES2 | c.76+13C>T | Intron (SNP) | VAF 32/190 reads (17%) | catalogued as rs1029113648; called by muse, mutect2, varscan2
- CLK2P1 | n.1079C>A | RNA (SNP) | VAF 64/419 reads (15%) | called by muse, mutect2, varscan2
- COL1A1 | chr17:50180713 G>T | 3'Flank (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- CWC27 | c.938+3383C>T | Intron (SNP) | VAF 10/170 reads (6%) | called by muse, mutect2
- CYFIP2 | c.3282+1034G>C | Intron (SNP) | VAF 21/170 reads (12%) | called by muse, mutect2, varscan2
- DLL1 | c.-24G>T | 5'UTR (SNP) | VAF 28/151 reads (19%) | called by muse, mutect2, varscan2
- EAF1 | c.-23G>T | 5'UTR (SNP) | VAF 25/260 reads (10%) | called by muse, mutect2
- FASN | c.6827-24G>A | Intron (SNP) | VAF 18/81 reads (22%) | catalogued as rs1239285311; called by muse, mutect2, varscan2
- FER1L4 | n.3038G>A | RNA (SNP) | VAF 11/175 reads (6%) | catalogued as rs1158876671; called by muse, mutect2
- FOXR1 | c.*17C>T | 3'UTR (SNP) | VAF 23/209 reads (11%) | called by muse, mutect2, varscan2
- GLA | c.640-12C>T | Intron (SNP) | VAF 39/237 reads (16%) | called by muse, mutect2, varscan2
- GPATCH8 | c.-31G>T | 5'UTR (SNP) | VAF 60/362 reads (17%) | called by muse, mutect2, varscan2
- HLA-F | chr6:29728042 G>C | 3'Flank (SNP) | VAF 17/289 reads (6%) | called by muse, mutect2
- IGKV1D-27 | n.255G>T | RNA (SNP) | VAF 60/465 reads (13%) | called by muse, mutect2, varscan2
- IL6ST | chr5:55995544 C>T | 5'Flank (SNP) | VAF 11/77 reads (14%) | called by muse, mutect2, varscan2
- KHSRP | chr19:6411766 G>C | 3'Flank (SNP) | VAF 7/60 reads (12%) | called by muse, mutect2, varscan2
- KIR2DL4 | c.*3G>T | 3'UTR (SNP) | VAF 23/220 reads (10%) | called by muse, mutect2, varscan2
- KRT6A | c.817-36G>A | Intron (SNP) | VAF 45/456 reads (10%) | called by muse, mutect2, varscan2
- LDB2 | c.891+2635G>T | Intron (SNP) | VAF 21/140 reads (15%) | called by muse, mutect2, varscan2
- LEMD3 | c.2127-10C>G | Intron (SNP) | VAF 14/215 reads (7%) | called by muse, mutect2
- LINC01567 | n.265C>T | RNA (SNP) | VAF 36/322 reads (11%) | called by muse, mutect2
- LMO2 | c.-272+662C>A | Intron (SNP) | VAF 32/167 reads (19%) | called by muse, mutect2, varscan2
- LY6G6E | c.*5C>T | 3'UTR (SNP) | VAF 21/54 reads (39%) | catalogued as rs531755764, COSV101011702; called by muse, mutect2, varscan2
- MAP1LC3C | c.*1C>G | 3'UTR (SNP) | VAF 5/57 reads (9%) | called by muse, mutect2
- MEFV | c.910+2132C>T | Intron (SNP) | VAF 16/124 reads (13%) | catalogued as rs1232821519; called by muse, varscan2
- MT3 | chr16:56589133 G>C | 5'Flank (SNP) | VAF 18/135 reads (13%) | catalogued as rs778043286; called by muse, mutect2, varscan2
- NOC2LP2 | n.906G>A | RNA (SNP) | VAF 26/342 reads (8%) | catalogued as rs764280558; called by muse, mutect2
- NPEPL1 | c.823-1622G>T | Intron (SNP) | VAF 26/198 reads (13%) | called by muse, mutect2, varscan2
- NPHP3 | c.3812+21C>A | Intron (SNP) | VAF 12/102 reads (12%) | catalogued as rs756756772; called by muse, mutect2
- NPIPB14P | n.359-12C>T | Intron (SNP) | VAF 34/492 reads (7%) | called by muse, mutect2
- NPIPB14P | n.279C>T | RNA (SNP) | VAF 34/604 reads (6%) | called by muse, mutect2
- NPIPP1 | chr16:15125705 C>A | 5'Flank (SNP) | VAF 25/291 reads (9%) | called by muse, mutect2, varscan2
- NTM-AS1 | n.2440C>T | RNA (SNP) | VAF 7/43 reads (16%) | called by muse, mutect2, varscan2
- OR51F5P | n.348A>T | RNA (SNP) | VAF 24/158 reads (15%) | called by muse, mutect2, varscan2
- OTUD7B | c.732+14G>T | Intron (SNP) | VAF 24/189 reads (13%) | called by muse, mutect2, varscan2
- PCF11 | c.2092+139C>T | Intron (SNP) | VAF 12/212 reads (6%) | catalogued as rs1410164489; called by muse, mutect2
- PLEKHM1P1 | n.2155G>A | RNA (SNP) | VAF 16/247 reads (6%) | catalogued as rs1268116711; called by muse, mutect2
- PSG8 | chr19:42753363 G>T | 3'Flank (SNP) | VAF 19/314 reads (6%) | catalogued as rs1301202083, COSV60609287; called by muse, mutect2
- RBM46 | c.1403-7479G>T | Intron (SNP) | VAF 17/118 reads (14%) | called by muse, mutect2, varscan2
- REG4 | c.165+13C>A | Intron (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2
- RNF207 | c.324+91G>T | Intron (SNP) | VAF 16/178 reads (9%) | called by muse, mutect2
- RNF207 | c.324+92G>T | Intron (SNP) | VAF 16/178 reads (9%) | called by muse, mutect2
- SENP7 | c.2481-15C>T | Intron (SNP) | VAF 10/116 reads (9%) | called by muse, mutect2
- SERF1A | c.116+3289G>T | Intron (SNP) | VAF 35/247 reads (14%) | called by muse, mutect2, varscan2
- SERPING1 | c.889+35C>G | Intron (SNP) | VAF 26/224 reads (12%) | catalogued as rs371517015; called by muse, mutect2, varscan2
- SFXN5 | c.945+4108G>A | Intron (SNP) | VAF 14/180 reads (8%) | called by muse, mutect2
- SHBG | chr17:7633378 A>C | 3'Flank (SNP) | VAF 22/338 reads (7%) | called by muse, mutect2
- SRP9 | c.-10C>G | 5'UTR (SNP) | VAF 10/184 reads (5%) | catalogued as COSV100504845; called by muse, mutect2
- VWA5B1 | c.2893+833C>T | Intron (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- XIAP | c.*3405G>T | 3'UTR (SNP) | VAF 13/118 reads (11%) | called by muse, mutect2, varscan2
- ZNF207 | chr17:32373373 A>T | 3'Flank (SNP) | VAF 13/97 reads (13%) | called by muse, mutect2, varscan2
- ZNRF1 | c.*46del | 3'UTR (DEL) | VAF 29/260 reads (11%) | called by mutect2, pindel, varscan2
